Somatic mutation profile of tumor specimen TARGET-10-PASSZA-09A (aliquot TARGET-10-PASSZA-09A-01D) from TARGET case TARGET-10-PASSZA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,416 days).
Specimen TARGET-10-PASSZA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4b7a2b9-49d6-4ffe-a5f7-f7e8ef7050d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASSZA-14A (Bone Marrow Normal), aliquot TARGET-10-PASSZA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4835d40c-4c0a-4d22-9910-55cb82de530d

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, Intron 2, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 43/213 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FAT2 | c.9763G>A p.V3255M | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV55832340; called by muse, mutect2, varscan2
- GEMIN4 | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | catalogued as rs774823238, COSV56748062; called by muse, mutect2, varscan2
- LIPK | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.74); catalogued as rs781481024, COSV68202097; called by muse, mutect2, varscan2
- MGA | c.7585dup p.R2529Kfs*9 (on ENST00000219905 / NM_001164273.1; = p.R2320Kfs*9 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- LCT | c.1659C>T p.T553= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs142388926, COSV99929842; called by muse, mutect2
- MAMDC4 | c.1908C>T p.N636= | Silent (SNP) | VAF 17/241 reads (7%) | catalogued as rs750997232; called by muse, mutect2
- PLCG2 | c.3276C>T p.A1092= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs774158419; called by muse, mutect2
- IGHV1-45 | chr14:106506995 ins GGGAAAGCC | 3'Flank (INS) | VAF 22/84 reads (26%) | called by mutect2, pindel*, varscan2
- MMAB | c.520-105A>G | Intron (SNP) | VAF 23/58 reads (40%) | catalogued as rs775694324; called by muse, mutect2, varscan2
- SPOCD1 | c.*14C>G | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- STAP2 | c.1073-106G>T | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as COSV55699606; called by muse, mutect2
